Somatic mutation profile of tumor specimen 0DSEL5 from CCDI case PBCHXI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 4.9 years (1,795 days).
Specimen 0DSEL5: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37e5f21d-4673-4dba-898f-b5210c2d9251.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEKW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41377b6c-f24c-46b2-94ae-31c9a1cc95e5

The open-access MAF lists 58 somatic variants for this specimen: 35 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Intron 7, Splice Site 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1527+1G>A p.X509_splice | Splice Site (SNP) | VAF 113/381 reads (30%) | catalogued as rs1060500331, CD000959, CS040856, CS086407, CS993383, COSV62203118, COSV62217322; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCE1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 42/738 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1449962421; called by muse, mutect2
- ADAM29 | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 370/692 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1165500074, COSV100822330; called by muse, mutect2, varscan2
- CLIP1 | c.3393G>C p.L1131F (on ENST00000620786 / NM_001247997.1; = p.L1120F on NM_002956.2) | Missense Mutation (SNP) | VAF 146/707 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.451); catalogued as COSV56798189; called by muse, mutect2, varscan2
- FAM83H | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 126/803 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as rs782591910, COSV66353653; called by muse, mutect2, varscan2
- GMFG | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1456493857; called by muse, mutect2, varscan2
- KIAA2026 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 142/477 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV67354097, COSV67356800; called by muse, mutect2, varscan2
- KLHL9 | c.1219C>G p.R407G | Missense Mutation (SNP) | VAF 209/540 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62921748; called by muse, mutect2, varscan2
- MERTK | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 143/557 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745461381, COSV54928816; called by muse, mutect2, varscan2
- MYOM2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 195/1651 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs147661043, COSV50717399; called by muse, mutect2, varscan2
- NAV3 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 168/852 reads (20%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.995); catalogued as rs1450212611; called by muse, mutect2, varscan2
- NF1 | c.7359C>A p.C2453* (on ENST00000358273 / NM_001042492.3; = p.C2432* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 155/527 reads (29%) | catalogued as CM030914, COSV62216009; called by muse, mutect2, varscan2
- PRAMEF4 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs1411748055, COSV52438052, COSV99339448; called by muse, mutect2, varscan2
- TECTA | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 154/837 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.444); catalogued as rs1243485512; called by muse, mutect2, varscan2
- ADPGK | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 117/336 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ALCAM | c.794A>T p.N265I | Missense Mutation (SNP) | VAF 146/433 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CA1 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 120/970 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYP2S1 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 160/448 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAH1 | c.5572C>T p.L1858F | Missense Mutation (SNP) | VAF 272/804 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- DPYD | c.1591G>T p.V531L | Missense Mutation (SNP) | VAF 251/654 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DSE | c.1049G>C p.R350P | Missense Mutation (SNP) | VAF 218/651 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGFR4 | c.1603A>C p.N535H | Missense Mutation (SNP) | VAF 379/497 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL2 | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 158/678 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FOCAD | c.3385T>A p.F1129I | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HPSE | c.1604G>T p.R535I | Missense Mutation (SNP) | VAF 124/557 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KANK1 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- KCNA6 | c.1373T>A p.V458D | Missense Mutation (SNP) | VAF 213/1186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMGT1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 160/444 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC2 | c.3208C>A p.P1070T | Missense Mutation (SNP) | VAF 123/649 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- NAA16 | c.307T>G p.Y103D | Missense Mutation (SNP) | VAF 77/400 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDC80 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 133/386 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTRK2 | c.1890-2A>G p.X630_splice (on ENST00000323115 / NM_001369534.1; = p.X646_splice on NM_006180.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 86/235 reads (37%) | called by muse, mutect2, varscan2
- OR2G6 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 166/452 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SPTBN1 | c.5254C>A p.Q1752K | Missense Mutation (SNP) | VAF 47/675 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.22); called by muse, mutect2
- ZIC5 | c.1903C>A p.L635I | Missense Mutation (SNP) | VAF 159/429 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ADGRA1 | c.729C>A p.A243= | Silent (SNP) | VAF 153/538 reads (28%) | called by muse, mutect2, varscan2
- CEP295 | c.6234G>C p.L2078= | Silent (SNP) | VAF 180/857 reads (21%) | catalogued as rs769853020; called by muse, mutect2, varscan2
- CRY2 | c.1185C>T p.S395= | Silent (SNP) | VAF 111/596 reads (19%) | catalogued as rs139676933; called by muse, mutect2, varscan2
- CSMD3 | c.6984T>A p.L2328= (on ENST00000297405 / NM_001363185.1; = p.L2224= on NM_052900.3) | Silent (SNP) | VAF 85/707 reads (12%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.720T>C p.F240= | Silent (SNP) | VAF 123/620 reads (20%) | catalogued as rs745360987, COSV60787858; called by muse, mutect2, varscan2
- DLC1 | c.2931C>T p.P977= (on ENST00000276297 / NM_001348081.2; = p.P540= on NM_006094.5) | Silent (SNP) | VAF 213/1484 reads (14%) | called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.420C>T p.C140= | Silent (SNP) | VAF 103/534 reads (19%) | catalogued as rs374760516, COSV60547916; called by muse, mutect2, varscan2
- FAM124A | c.1239C>T p.D413= (on ENST00000322475 / NM_001242312.2; = p.D449= on NM_145019.4) | Silent (SNP) | VAF 129/409 reads (32%) | catalogued as rs373223015; called by muse, mutect2, varscan2
- GLIPR1 | c.789T>G p.V263= | Silent (SNP) | VAF 78/534 reads (15%) | called by muse, mutect2, varscan2
- GPAT3 | c.841C>T p.L281= | Silent (SNP) | VAF 128/674 reads (19%) | called by muse, mutect2, varscan2
- LHPP | c.243C>A p.T81= | Silent (SNP) | VAF 134/433 reads (31%) | called by muse, mutect2, varscan2
- MBOAT1 | c.987G>C p.S329= | Silent (SNP) | VAF 49/812 reads (6%) | catalogued as COSV61126136; called by muse, mutect2
- SCYL3 | c.660C>A p.T220= | Silent (SNP) | VAF 168/555 reads (30%) | catalogued as COSV63047041; called by mutect2, varscan2
- SEMA3G | c.1536G>T p.L512= | Silent (SNP) | VAF 102/728 reads (14%) | called by muse, mutect2, varscan2
- TAB3 | c.72A>T p.P24= | Silent (SNP) | VAF 42/745 reads (6%) | called by muse, mutect2
- AFDN | c.2037+57C>G | Intron (SNP) | VAF 70/160 reads (44%) | called by muse, mutect2, varscan2
- EGFR | c.1881-789G>C | Intron (SNP) | VAF 208/928 reads (22%) | catalogued as COSV51780511, COSV51793482; called by muse, mutect2, varscan2
- EPCAM | c.-89C>A | 5'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- LRRC6 | c.11-31G>T | Intron (SNP) | VAF 55/364 reads (15%) | called by muse, mutect2, varscan2
- MORN1 | c.149-24T>G | Intron (SNP) | VAF 50/142 reads (35%) | called by muse, mutect2, varscan2
- MTFR1 | c.67-21C>T | Intron (SNP) | VAF 150/670 reads (22%) | catalogued as rs199795578; called by muse, mutect2, varscan2
- PRPF31 | c.528-69G>T | Intron (SNP) | VAF 28/87 reads (32%) | catalogued as COSV58084582; called by muse, mutect2, varscan2
- RNF212 | c.246+2954C>T | Intron (SNP) | VAF 112/529 reads (21%) | catalogued as rs779483360; called by muse, mutect2, varscan2
